Somatic mutation profile of tumor specimen C3L-02704-71 (aliquot CPT0189750007) from CPTAC case C3L-02704, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.4 years (19,879 days).
Specimen C3L-02704-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33de8224-021b-4ffa-bf9f-ea75553e34f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02704-31 (Blood Derived Normal), aliquot CPT0190660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e530cf0-0b81-4ae0-8f72-108cb7a5bae1

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Intron 2, Nonsense Mutation 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>A p.A289D | Missense Mutation (SNP) | VAF 5502/5948 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- AMDHD1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 64/193 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.358); catalogued as rs750280428, COSV57138427; called by muse, mutect2, varscan2
- AMER1 | c.1500C>G p.Y500* | Nonsense Mutation (SNP) | VAF 34/43 reads (79%) | catalogued as COSV57655865; called by muse, mutect2, varscan2
- DROSHA | c.4009A>G p.M1337V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs761344878; called by muse, mutect2, varscan2
- DYNC1I1 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as rs201114371, COSV61456326; called by muse, mutect2, varscan2
- EGFR | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 1292/4649 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567477136, COSV51777313, COSV51843665; called by muse, mutect2, varscan2
- NEPRO | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs202154386; called by muse, mutect2, varscan2
- OR4K13 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs199734457; called by muse, mutect2, varscan2
- PARP1 | c.926A>G p.Y309C | Missense Mutation (SNP) | VAF 101/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761098347; called by muse, mutect2, varscan2
- PIWIL1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.32); catalogued as rs755399300, COSV55348877; called by muse, mutect2, varscan2
- ZKSCAN8 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs768465659; called by muse, mutect2, varscan2
- CHD8 | c.4886C>T p.A1629V (on ENST00000646647 / NM_001170629.2; = p.A1350V on NM_020920.4) | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- COL27A1 | c.2290C>T p.L764F | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2
- CUL7 | c.5074C>T p.Q1692* | Nonsense Mutation (SNP) | VAF 100/296 reads (34%) | called by muse, mutect2, varscan2
- ESR2 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IBTK | c.3413C>T p.T1138I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.046); called by muse, varscan2
- IMPG2 | c.770A>C p.E257A | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- KANSL3 | c.2293A>C p.T765P (on ENST00000666923 / NM_001349262.2; = p.T739P on NM_001115016.3) | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNQ5 | c.2147T>A p.V716E | Missense Mutation (SNP) | VAF 122/209 reads (58%) | SIFT tolerated (0.91); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- KMT2A | c.4432_4434del p.R1478del | In Frame Del (DEL) | VAF 24/122 reads (20%) | called by pindel, varscan2
- KRTAP10-9 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MAP3K21 | c.703C>A p.H235N | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- NACA2 | c.170C>G p.A57G | Missense Mutation (SNP) | VAF 140/375 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- NFIC | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP19 | c.3463A>T p.I1155F | Missense Mutation (SNP) | VAF 186/287 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AKT2 | c.792G>A p.E264= | Silent (SNP) | VAF 196/571 reads (34%) | catalogued as rs182481170; called by muse, mutect2, varscan2
- ANKRD62 | c.237G>A p.A79= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as rs762385517, COSV100019087, COSV58412222; called by muse, mutect2, varscan2
- COL27A1 | c.2289G>A p.G763= | Silent (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
- DEGS2 | c.222C>T p.Y74= | Silent (SNP) | VAF 152/444 reads (34%) | catalogued as rs568514624; called by muse, mutect2, varscan2
- FCGBP | c.6858G>A p.A2286= | Silent (SNP) | VAF 99/1662 reads (6%) | catalogued as rs1387463721; called by muse, mutect2
- HGFAC | c.1812C>T p.C604= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as rs994224938; called by muse, mutect2, varscan2
- MYH4 | c.5712G>A p.Q1904= | Silent (SNP) | VAF 16/199 reads (8%) | called by muse, mutect2
- PROZ | c.567G>A p.P189= | Silent (SNP) | VAF 189/597 reads (32%) | catalogued as rs146163809; called by muse, mutect2, varscan2
- S1PR1 | c.999C>T p.S333= | Silent (SNP) | VAF 64/193 reads (33%) | catalogued as rs767575855; called by muse, mutect2, varscan2
- COL6A6 | c.4533+28T>G | Intron (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- FAM183BP | n.896C>T | RNA (SNP) | VAF 90/229 reads (39%) | catalogued as rs773686260; called by muse, mutect2, varscan2
- IBTK | c.3431+43C>G | Intron (SNP) | VAF 38/89 reads (43%) | catalogued as rs199801194; called by muse, varscan2
- RNF217-AS1 | n.1681G>T | RNA (SNP) | VAF 7/54 reads (13%) | catalogued as rs561192043; called by muse, mutect2, varscan2
